Somatic mutation profile of tumor specimen MBCProject_0799_T2_WES (aliquot MBCProject_0799_T2_WES_1) from CMI case MBCProject_0799, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.5 years (20,631 days).
Specimen MBCProject_0799_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d36166e9-844e-4b60-8858-d2b4197660c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0799_SALIVA (Saliva), aliquot MBCProject_0799_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feaeef7a-d650-457a-86a5-770a79e408c6

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, RNA 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 38/178 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 139/253 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP2B3 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs2269409; called by muse, mutect2, varscan2
- CBFB | c.165C>A p.I55= | Splice Region (SNP) | VAF 95/165 reads (58%) | catalogued as rs780403146; called by muse, mutect2, varscan2
- CTAG2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs1158536572, COSV55994412; called by muse, mutect2, varscan2
- ESX1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV101006430; called by muse, mutect2, varscan2
- IGF2R | c.6296C>T p.T2099M | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755610532; called by muse, mutect2, varscan2
- KCNC2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 114/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54371719; called by muse, mutect2, varscan2
- KCNQ2 | c.2120C>T p.A707V (on ENST00000359125 / NM_172107.4; = p.A679V on NM_004518.6) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753033741; called by muse, mutect2, varscan2
- KCP | c.3982C>T p.R1328* (on ENST00000620378; = p.R1452* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as rs1469870148; called by muse, mutect2, varscan2
- MBTPS1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as COSV58572584; called by muse, mutect2, varscan2
- PHOX2B | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.114); catalogued as COSV56930741; called by muse, varscan2
- PROS1 | c.1660G>T p.V554F | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV101260915; called by muse, mutect2, varscan2
- SEMA3C | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs776985479; called by muse, varscan2
- SIRPG | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 45/443 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1262888704; called by muse, mutect2, varscan2
- ARID1A | c.713_720del p.T238Ifs*159 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- CBFB | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CDAN1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MAP3K1 | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 82/111 reads (74%) | called by muse, mutect2, varscan2
- NRXN3 | c.1267G>A p.A423T (on ENST00000335750 / NM_001330195.2; = p.A50T on NM_004796.6) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDYN | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PITX3 | c.281dup p.I95Dfs*167 | Frame Shift Ins (INS) | VAF 57/289 reads (20%) | called by mutect2, pindel, varscan2
- SLC35E1 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 80/307 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SLC35G2 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC35G2 | c.982T>G p.S328A | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF418 | c.1273C>A p.P425T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASXL3 | c.4779A>G p.A1593= | Silent (SNP) | VAF 38/254 reads (15%) | called by muse, mutect2, varscan2
- HGSNAT | c.549G>C p.L183= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- HMCN2 | c.4704C>T p.D1568= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as rs1040501756; called by muse, mutect2, varscan2
- ITGA9 | c.1392G>A p.T464= | Silent (SNP) | VAF 57/325 reads (18%) | catalogued as rs770099797; called by muse, mutect2, varscan2
- MCF2L | c.1971C>T p.Y657= (on ENST00000375608; = p.Y625= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as rs368629853; called by muse, varscan2
- MRPL1 | c.72T>C p.V24= | Silent (SNP) | VAF 43/256 reads (17%) | called by muse, mutect2, varscan2
- MYO5C | c.1620A>G p.R540= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- MYRIP | c.1995G>A p.G665= | Silent (SNP) | VAF 84/193 reads (44%) | called by muse, mutect2, varscan2
- SDK1 | c.6498G>A p.A2166= | Silent (SNP) | VAF 82/534 reads (15%) | catalogued as rs778396777, COSV67360806; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2947G>A | Intron (SNP) | VAF 183/537 reads (34%) | catalogued as rs747921046, COSV58442745; called by muse, mutect2, varscan2
- MIRLET7A2 | n.45G>T | RNA (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- RP2 | c.-13G>A | 5'UTR (SNP) | VAF 94/534 reads (18%) | called by muse, mutect2, varscan2
